Gene-level copy-number profile of tumor specimen ALCH-B1VW-TTR1-A from ALCHEMIST case ALCH-B1VW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.0 years (24,847 days).
Specimen ALCH-B1VW-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4e08237a-5c39-4cac-b8bf-a0c26886cae6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1VW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/2dd36676-fb78-48a7-b8ff-3703e1f041f1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 179; copy number 1: 7,431; copy number 2: 49,785; copy number 3: 935; copy number 4: 34; copy number 5: 7; copy number 6: 4; copy number 7: 3; copy number 17: 8.

Homozygous deletions (total copy number 0; autosomes only): 129 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,527,724–12,528,420, 1 gene: LINC02766.
- chr1:12,773,738–12,823,159, 3 genes: PRAMEF12, PRAMEF1, LINC01784.
- chr1:12,922,554–12,928,253, 2 genes (within-gene range 0–1): RNU6-1072P, PRAMEF29P.
- chr1:55,039,447–55,064,852, 1 gene: PCSK9.
- chr2:90,100,236–90,173,414, 6 genes (within-gene range 0–1): IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11.
- chr2:96,875,882–97,009,104, 6 genes (within-gene range 0–2): FAM178B, AC092636.1, Metazoa_SRP, RNA5SP101, AC079395.3, AC079395.2.
- chr2:231,706,895–231,713,551, 3 genes: PTMA, U4, MIR1244-1.
- chr3:46,694,528–46,710,886, 1 gene: TMIE.
- chr4:8,846,076–8,871,839, 2 genes: HMX1, AC116612.1.
- chr4:188,091,273–188,109,603, 2 genes: TRIML2, AC108073.2.
- chr6:106,969,831–107,051,586, 2 genes: CD24, MTRES1.
- chr7:152,445,477–152,465,549, 2 genes: CCT8L1P, LINC01003.
- chr9:130,400,266–130,400,565, 1 gene (within-gene range 0–2): RN7SL665P.
- chr10:42,242,721–42,276,842, 1 gene: AL031601.2.
- chr14:93,138,066–93,138,465, 1 gene: CYB5AP3.
- chr15:25,180,497–25,250,940, 39 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:41,493,393–41,513,887, 2 genes: ITPKA, LTK.
- chr15:64,701,248–64,719,602, 1 gene (within-gene range 0–2): AC100830.1.
- chr16:14,275,508–14,418,908, 6 genes: Y_RNA, MIR193BHG, MIR193B, MIR365A, LINC02130, AC040173.1.
- chr16:83,899,115–84,045,333, 7 genes (within-gene range 0–2): MLYCD, AC009119.2, OSGIN1, NECAB2, SLC38A8, RNA5SP432, AC040169.4.
- chr17:142,789–386,254, 7 genes: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3.
- chr17:2,712,309–3,037,741, 7 genes (within-gene range 0–2): AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253, RAP1GAP2, AC015921.1.
- chr17:3,662,895–3,801,188, 9 genes: TAX1BP3, P2RX5-TAX1BP3, AC132942.1, EMC6, P2RX5, ITGAE, AC116914.2, HASPIN, AC116914.1.
- chr17:9,244,666–9,244,897, 1 gene: AC005695.3.
- chr19:186,373–246,544, 4 genes: SEPTIN14P19, CICP19, LINC01002, RNU6-1076P.
- chr19:361,747–399,173, 2 genes: THEG, AC010641.1.
- chr19:6,306,142–6,412,404, 10 genes: ACER1, AC011491.3, CLPP, ALKBH7, PSPN, GTF2F1, AC011491.2, MIR6885, MIR6790, AC011491.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 22 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–13,155,961, 8 genes, copy number 17 (within-gene range 1–17): PRAMEF6, PRAMEF28P, PRAMEF27, HNRNPCL3, PRAMEF25, PRAMEF35P, HNRNPCL2, PRAMEF26.
- chr4:1,113,639–1,153,726, 4 genes, copy number 6: AC092535.4, TMED11P, AC092535.1, AC092535.2.
- chr14:105,398,538–105,450,106, 2 genes, copy number 5 (within-gene range 3–5): TEX22, AL928654.1.
- chr14:105,472,962–105,492,267, 3 genes, copy number 7 (within-gene range 4–7): CRIP2, CRIP1, AL928654.3.
- chr20:50,510,321–50,585,241, 4 genes, copy number 5: PTPN1, RN7SL672P, Y_RNA, AL133230.1.
- chr22:45,657,019–45,680,130, 1 gene, copy number 5 (within-gene range 4–5): Z95331.1.

Autosomal genes at a single copy (total copy number 1): 5,674. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
